Gene-level copy-number profile of tumor specimen TCGA-YL-A9WI-01A from TCGA case TCGA-YL-A9WI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,184 days).
Specimen TCGA-YL-A9WI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.221c55a6-dbf4-4dd0-9000-addd29d67f35.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YL-A9WI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ab64a01-b7a2-41f8-8b51-b363f49a0c28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 5,272; copy number 2: 37,831; copy number 3: 15,248; copy number 4: 1,304; copy number 5: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YL-A9WI-01A-11D-A376-01): tumor purity 0.88, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:142,131,178–143,819,599, 22 genes: AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1, ARHGAP15, MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1, AC079793.1, AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2, AC079584.1.
- chr2:146,145,156–146,194,821, 2 genes: RNU7-2P, RPL17P12.
- chr5:90,388,468–90,529,584, 6 genes: AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3.
- chr5:98,085,866–100,903,282, 49 genes (within-gene range 0–1): LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P.
- chr6:112,616,703–114,471,705, 23 genes (within-gene range 0–1): PA2G4P5, AL360085.1, RNU6-1163P, AL360015.1, FCF1P10, AL049695.1, SOCS5P5, AL589684.1, LINC02518, AL513123.1, RPS27AP11, LINC02541, FO393415.2, FO393415.1, MARCKS, MROCKI, LINC02880, HDAC2, HDAC2-AS2, NUDT19P3, HS3ST5, RPSAP43, RNA5SP213.
- chr6:114,822,994–116,249,497, 10 genes (within-gene range 0–1): AL590550.1, RNU6-475P, AL606845.1, LINC02534, FRK, AL357141.1, TPI1P3, NT5DC1, COL10A1, NIP7P3.
- chr6:121,542,486–121,858,768, 7 genes: RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:62,221,249–64,688,000, 38 genes, copy number 5 (within-gene range 3–5): PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1.

Autosomal genes at a single copy (total copy number 1): 2,886. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
